Somatic mutation profile of tumor specimen TCGA-CM-4746-01A (aliquot TCGA-CM-4746-01A-01D-1408-10) from TCGA case TCGA-CM-4746, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage I; Age at diagnosis: 61.3 years (22,403 days).
Specimen TCGA-CM-4746-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1746b7a3-bc62-4573-b4bd-41068c57510e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-4746-10A (Blood Derived Normal), aliquot TCGA-CM-4746-10A-01D-1408-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3284616-431e-4a2e-8bc0-21cfbd68f2db

The open-access MAF lists 880 somatic variants for this specimen: 678 protein-altering or splice-affecting, 185 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 477, Silent 185, Frame Shift Del 112, Frame Shift Ins 37, Nonsense Mutation 30, Splice Site 11, Intron 8, Splice Region 6, In Frame Del 5, 3'UTR 5, RNA 3, 5'Flank 1.

Variants (750 of 880; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1742del p.K581Rfs*9 | Frame Shift Del (DEL) | VAF 50/157 reads (32%) | catalogued as rs1060503259, CM1110730, COSV57340306; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BCKDHB | c.1016C>T p.S339L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as rs398124561, CM016176, COSV57511452; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CNGB3 | c.1285del p.S429Lfs*9 | Frame Shift Del (DEL) | VAF 44/161 reads (27%) | catalogued as rs776896038; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- DNAH8 | c.1768C>T p.R590* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as rs567050969, CM144220, COSV100547071; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- DUSP16 | c.1447C>T p.R483* | Nonsense Mutation (SNP) | VAF 39/90 reads (43%) | hotspot (GDC flag); catalogued as COSV53806110; called by muse, mutect2, varscan2
- FLNB | c.1592dup p.H532Tfs*9 | Frame Shift Ins (INS) | VAF 7/19 reads (37%) | catalogued as rs746105983; ClinVar: pathogenic; called by mutect2, varscan2
- GAA | c.258dup p.N87Qfs*9 | Frame Shift Ins (INS) | VAF 10/22 reads (45%) | catalogued as rs761317813; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 18/46 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- MAK | c.814C>T p.R272* | Nonsense Mutation (SNP) | VAF 25/80 reads (31%) | catalogued as rs753314164, COSV57564849; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MLH1 | c.860del p.N287Tfs*10 | Frame Shift Del (DEL) | VAF 34/114 reads (30%) | catalogued as rs63750034, CM973728; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MOCS2 | c.65dup p.L23Ifs*5 | Frame Shift Ins (INS) | VAF 13/30 reads (43%) | catalogued as rs398122799; ClinVar: pathogenic; called by mutect2, varscan2
- NGLY1 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201791209, CM154997, COSV54985436; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3139C>T p.H1047Y | Missense Mutation (SNP) | VAF 21/59 reads (36%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen benign (0); catalogued as rs121913281, CM126699, COSV55876499, COSV55912376; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- POGZ | c.3022C>T p.R1008* | Nonsense Mutation (SNP) | VAF 17/102 reads (17%) | catalogued as rs1085307702, CM162609, COSV51851135; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STAT5B | c.1102del p.Q368Rfs*2 | Frame Shift Del (DEL) | VAF 28/79 reads (35%) | catalogued as rs761761205; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 66/71 reads (93%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.1883C>T p.A628V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs1057212368, COSV100933222; called by muse, mutect2
- ABCC9 | c.2816G>A p.R939Q | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.217); catalogued as rs748770166, COSV53967417; called by muse, mutect2, varscan2
- ABCF3 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs772268623, COSV53047668; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.1628G>A p.R543H | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779815701, COSV53685808; called by muse, mutect2, varscan2
- ABHD2 | c.697G>A p.V233M | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.21); catalogued as rs150079355, COSV61773504; called by muse, mutect2, varscan2
- ABHD8 | c.989C>A p.A330D | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs778402701, COSV99917358; called by muse, mutect2, varscan2
- ACAN | c.7288G>T p.D2430Y (on ENST00000560601 / NM_001369268.1; = p.D2354Y on NM_001135.3) | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61358791, COSV61358872; called by muse, mutect2, varscan2
- ACAP3 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs1388963411, COSV61221949; called by muse, mutect2, varscan2
- ACKR1 | c.275T>C p.L92P | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV63672449; called by muse, mutect2, varscan2
- ACRBP | c.1592G>T p.S531I | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV57523521; called by muse, mutect2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ACVR2B | c.1240T>G p.F414V | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61701891; called by muse, mutect2, varscan2
- ADA2 | c.332T>C p.L111S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99376421; called by mutect2, varscan2
- ADAMTS10 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54353532; called by muse, mutect2, varscan2
- ADCK5 | c.1231G>A p.A411T | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.559); catalogued as rs1334562446, COSV100450687; called by muse, mutect2, varscan2
- ADCY10 | c.4790dup p.N1597Kfs*8 | Frame Shift Ins (INS) | VAF 61/294 reads (21%) | catalogued as rs753500756; called by mutect2, varscan2
- ADCY3 | c.1665C>A p.A555= | Splice Region (SNP) | VAF 13/25 reads (52%) | catalogued as COSV53166244; called by muse, mutect2, varscan2
- ADCY6 | c.1892C>T p.A631V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57167090; called by muse, mutect2, varscan2
- ADCY7 | c.1319C>T p.P440L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.445); catalogued as COSV54265770; called by muse, mutect2, varscan2
- ADGRV1 | c.15255G>T p.E5085D | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV67982874; called by muse, mutect2, varscan2
- ADSL | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.076); catalogued as COSV53407331, COSV53410457; called by muse, mutect2, varscan2
- AFF4 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 88/222 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs780771766, COSV54793422; called by muse, mutect2, varscan2
- AFG3L2 | c.1796G>A p.R599H | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1263405472, COSV52313883; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGBL5 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs955009057, COSV59936213; called by muse, mutect2, varscan2
- AGO3 | c.2531C>T p.A844V | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.175); catalogued as COSV55790847; called by muse, mutect2, varscan2
- AGRN | c.3003dup p.G1002Rfs*58 | Frame Shift Ins (INS) | VAF 14/60 reads (23%) | catalogued as rs763573703; called by mutect2, varscan2
- AHCY | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.156); catalogued as rs375760628; called by muse, mutect2, varscan2
- AHCY | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.318); catalogued as rs563484762, CM1513675, COSV54152966; called by muse, mutect2, varscan2
- AHNAK | c.8254G>A p.A2752T | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs752833516, COSV57209488; called by muse, mutect2, varscan2
- AK9 | c.3398C>T p.A1133V | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.028); catalogued as rs781295601, COSV58140769; called by muse, mutect2, varscan2
- AKAP13 | c.3623C>T p.A1208V | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV100774521; called by muse, mutect2, varscan2
- AKAP17A | c.1822C>T p.R608W | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs375125397, COSV100002218; called by muse, mutect2
- AKAP9 | c.11307dup p.Q3770Afs*52 (on ENST00000359028; = p.Q3746Afs*52 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 14/48 reads (29%) | catalogued as rs747796926; called by mutect2, varscan2
- ALDH4A1 | c.109G>A p.V37I | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs746845254, COSV99312285; called by muse, varscan2
- ALDH8A1 | c.936A>T p.R312S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as COSV55641126; called by muse, mutect2, varscan2
- ALPG | c.1514C>T p.A505V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99779468; called by muse, mutect2, varscan2
- ALPK1 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.919); catalogued as rs747393894, COSV51583869; called by muse, mutect2, varscan2
- ALPK3 | c.3152G>A p.G1051D | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV51932114; called by muse, mutect2, varscan2
- AMH | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as rs371130597, COSV55554201, COSV99678191; called by muse, mutect2
- AMIGO2 | c.758A>G p.D253G | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV99873812; called by muse, mutect2, varscan2
- ANGPT2 | c.1369G>A p.G457R | Missense Mutation (SNP) | VAF 82/278 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57336111; called by muse, mutect2, varscan2
- ANK2 | c.4212dup p.A1405Cfs*6 | Frame Shift Ins (INS) | VAF 28/72 reads (39%) | catalogued as rs763282994; called by mutect2, varscan2
- ANKLE2 | c.1138A>G p.M380V | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV61708772; called by muse, mutect2, varscan2
- ANKRD28 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 14/34 reads (41%) | catalogued as COSV67517539; called by muse, mutect2, varscan2
- ANO5 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs772899863, COSV61082332; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOBEC3H | c.26T>C p.F9S | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62378634; called by muse, mutect2, varscan2
- APOBR | c.1514C>A p.A505D (on ENST00000431282; = p.A514D on NM_018690.4) | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV60489873; called by muse, mutect2, varscan2
- APP | c.948T>A p.C316* | Nonsense Mutation (SNP) | VAF 28/59 reads (47%) | catalogued as COSV60996948; called by muse, mutect2, varscan2
- ARAP1 | c.4322C>T p.A1441V (on ENST00000393609 / NM_001040118.2; = p.A1196V on NM_015242.4) | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as rs371806185; called by muse, mutect2, varscan2
- ARHGEF19 | c.1360G>A p.V454M | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.384); catalogued as rs772652968, COSV54616068; called by muse, mutect2, varscan2
- ARHGEF26 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as COSV62845345; called by muse, mutect2, varscan2
- ARHGEF5 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 92/468 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99283122; called by muse, mutect2, varscan2
- ARMC7 | c.50T>C p.L17P | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55460688; called by muse, mutect2, varscan2
- ARMH3 | c.1322G>A p.R441H | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as rs763192348, COSV64234193; called by muse, mutect2, varscan2
- ARNT | c.218G>T p.R73L | Missense Mutation (SNP) | VAF 63/241 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62230286; called by muse, mutect2, varscan2
- ARNTL2 | c.1484C>T p.S495F | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV53824850; called by muse, mutect2, varscan2
- ATG2A | c.5497C>T p.R1833C | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1280110005, COSV65966325; called by muse, mutect2, varscan2
- ATP1A2 | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as CM139985, COSV63403248; called by muse, mutect2, varscan2
- ATP1A3 | c.1158G>T p.Q386H (on ENST00000545399 / NM_001256214.2; = p.Q373H on NM_152296.5) | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57491707; called by muse, mutect2
- ATP6V1G3 | c.137A>G p.Q46R | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.602); catalogued as COSV55278943; called by muse, mutect2, varscan2
- ATRX | c.7053G>T p.E2351D | Missense Mutation (SNP) | VAF 25/32 reads (78%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.474); catalogued as COSV64874486; called by muse, mutect2, varscan2
- ATXN7L2 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV63992183; called by muse, mutect2, varscan2
- AXIN1 | c.2534C>T p.A845V | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.458); catalogued as rs1567254724, COSV51985829; called by muse, mutect2, varscan2
- BABAM2 | c.790G>A p.V264M | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.933); catalogued as rs746140512, COSV59620366; called by muse, mutect2, varscan2
- BAHCC1 | c.3963del p.S1322Afs*42 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | catalogued as COSV57031311; called by mutect2, pindel, varscan2
- BCAT1 | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as rs749915074, COSV53909891; called by muse, mutect2, varscan2
- BCCIP | c.524C>A p.P175H | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.9); catalogued as COSV99501922; called by muse, mutect2, varscan2
- BCL9L | c.3588del p.P1198Lfs*5 | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | catalogued as rs1555172907; called by mutect2, pindel, varscan2
- BIRC6 | c.4051C>A p.L1351I | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV70197729; called by muse, mutect2, varscan2
- BMP1 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs201377252; called by muse, mutect2, varscan2
- BMP7 | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs372973923; called by muse, mutect2, varscan2
- BMP7 | c.881C>T p.T294M | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as rs761254136, COSV67779805, COSV67780275; called by muse, mutect2, varscan2
- BRD2 | c.1329G>T p.Q443H | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV66372976; called by muse, mutect2, varscan2
- BRF1 | c.1900G>A p.V634M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); catalogued as rs777504331, COSV59267810; called by muse, mutect2, varscan2
- BZW1 | c.104del p.C35Lfs*6 | Frame Shift Del (DEL) | VAF 22/68 reads (32%) | catalogued as COSV63349625; called by mutect2, pindel, varscan2
- C10orf90 | c.449del p.P150Qfs*58 | Frame Shift Del (DEL) | VAF 16/43 reads (37%) | catalogued as rs762432781; called by pindel, varscan2
- C10orf90 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760735148, COSV52950749; called by muse, varscan2
- C11orf1 | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 21/43 reads (49%) | catalogued as rs782010241, COSV52787941; called by muse, mutect2, varscan2
- C19orf25 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs768708385, COSV52017383, COSV99279920; called by muse, mutect2, varscan2
- C1orf87 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs757474276, COSV100967242; called by muse, mutect2
- CACNA1B | c.5945G>A p.R1982Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs200719516, COSV53121260; called by muse, mutect2, varscan2
- CACNA2D2 | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs747629573, COSV56562296; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CALHM1 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs146869547, COSV61707279; called by muse, mutect2, varscan2
- CALHM2 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.197); catalogued as rs369692383; called by muse, mutect2, varscan2
- CAPRIN1 | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1394809909, COSV58219309; called by muse, mutect2, varscan2
- CARD11 | c.2335C>T p.R779W | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62754451, COSV62755419; called by muse, mutect2, varscan2
- CATIP | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs746655964, COSV56822431; called by muse, mutect2
- CCAR2 | c.2683C>T p.R895C | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as rs556131395, COSV52383824; called by muse, mutect2, varscan2
- CCDC69 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.76); PolyPhen benign (0.011); catalogued as COSV62599513; called by muse, mutect2, varscan2
- CCDC73 | c.1913del p.N638Ifs*18 | Frame Shift Del (DEL) | VAF 46/140 reads (33%) | catalogued as rs762553129; called by mutect2, varscan2
- CCDC88A | c.3082A>G p.N1028D | Missense Mutation (SNP) | VAF 58/205 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV55059632; called by muse, mutect2, varscan2
- CD99 | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); catalogued as rs770516694, COSV66989316; called by muse, mutect2, varscan2
- CDH2 | c.1532A>G p.H511R | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV52276577; called by muse, mutect2, varscan2
- CDK11B | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58337706; called by muse, mutect2, varscan2
- CDK11B | c.1637T>A p.L546Q | Missense Mutation (SNP) | VAF 58/207 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58337720; called by muse, varscan2
- CDK12 | c.1987C>T p.R663C | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs749022057, COSV71000100; called by muse, mutect2, varscan2
- CDK20 | c.955del p.H319Tfs*16 (on ENST00000325303 / NM_001039803.3; = p.H298Tfs*16 on NM_012119.4) | Frame Shift Del (DEL) | VAF 16/98 reads (16%) | catalogued as rs749463697; called by mutect2, pindel, varscan2
- CDK8 | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 13/29 reads (45%) | catalogued as rs181880846, COSV101037124, COSV67420054; called by muse, mutect2, varscan2
- CEP152 | c.3661T>A p.L1221I (on ENST00000380950 / NM_001194998.2; = p.L1165I on NM_014985.4) | Missense Mutation (SNP) | VAF 105/239 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57858423; called by muse, mutect2, varscan2
- CEP250 | c.623A>G p.E208G | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61169263; called by muse, mutect2, varscan2
- CEP250 | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.097); catalogued as rs200183326, COSV61169267; called by muse, mutect2, varscan2
- CEP290 | c.635del p.N212Tfs*14 | Frame Shift Del (DEL) | VAF 21/72 reads (29%) | catalogued as rs769091629, COSV99063658; called by mutect2, varscan2
- CEP350 | c.8597C>T p.A2866V | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs760162188, COSV62600706; called by muse, mutect2, varscan2
- CERCAM | c.1585G>A p.A529T | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as rs770509829, COSV65710760; called by muse, mutect2, varscan2
- CGNL1 | c.838C>T p.R280* | Nonsense Mutation (SNP) | VAF 17/48 reads (35%) | catalogued as COSV55565812; called by muse, mutect2, varscan2
- CHD4 | c.3980G>A p.R1327H (on ENST00000357008 / NM_001363606.2; = p.R1340H on NM_001273.5) | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58898406; called by muse, mutect2, varscan2
- CHD5 | c.812C>T p.T271M | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs759139485, COSV52411998; called by muse, mutect2, varscan2
- CHD8 | c.3376C>T p.Q1126* (on ENST00000646647 / NM_001170629.2; = p.Q847* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 31/77 reads (40%) | catalogued as rs1555314976, COSV67870179; called by muse, mutect2, varscan2
- CHST1 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57321989; called by muse, mutect2, varscan2
- CHSY1 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 156/392 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.166); catalogued as rs773884567, COSV54252346; called by muse, mutect2, varscan2
- CHTF18 | c.1825G>A p.A609T | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs377736001, COSV50210141; called by muse, mutect2, varscan2
- CLDN10 | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.363); catalogued as COSV65296426; called by muse, mutect2, varscan2
- CLDN8 | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 68/187 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs778089405, COSV54525752; called by muse, mutect2, varscan2
- CLEC16A | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0.091); catalogued as rs775872909, COSV68499067; called by muse, mutect2, varscan2
- CLUAP1 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs531380218, COSV58892460; called by muse, mutect2, varscan2
- CMBL | c.460G>A p.V154I | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as rs780957157, COSV56982742, COSV56982761; called by muse, mutect2, varscan2
- CMSS1 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as rs776581370, COSV70435635, COSV70438159; called by muse, mutect2, varscan2
- CNKSR1 | c.1810C>T p.R604W (on ENST00000374253 / NM_001297647.2; = p.R597W on NM_006314.3) | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761159609, COSV58792759; called by muse, mutect2, varscan2
- COL4A4 | c.1129C>A p.R377S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.118); catalogued as COSV61631111; called by muse, mutect2, varscan2
- COL9A2 | c.1636C>T p.R546W | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs772278003, COSV65622462; called by muse, mutect2, varscan2
- COQ4 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 13/28 reads (46%) | catalogued as COSV55956747; called by muse, mutect2, varscan2
- CORIN | c.2445G>A p.W815* | Nonsense Mutation (SNP) | VAF 26/68 reads (38%) | catalogued as COSV56689403; called by muse, mutect2, varscan2
- CPNE3 | c.266T>C p.L89P | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV52205550; called by muse, mutect2, varscan2
- CPPED1 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); catalogued as rs367880734; called by muse, mutect2, varscan2
- CPS1 | c.4292G>A p.S1431N | Missense Mutation (SNP) | VAF 78/212 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs754446815, COSV51806630; called by muse, mutect2, varscan2
- CPSF1 | c.3578G>A p.W1193* | Nonsense Mutation (SNP) | VAF 12/47 reads (26%) | catalogued as COSV58233106; called by muse, mutect2, varscan2
- CRTC3 | c.1813C>A p.L605M | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51595580; called by muse, mutect2, varscan2
- CST11 | c.362C>T p.A121V (on ENST00000377009 / NM_130794.2; = p.A86V on NM_080830.3) | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.97); PolyPhen benign (0.015); catalogued as COSV65440645, COSV65440671; called by muse, mutect2, varscan2
- CSTF1 | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1251578127, COSV53858290; called by muse, mutect2, varscan2
- CTDSP2 | c.515C>A p.P172H | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66079886; called by muse, mutect2, varscan2
- CTDSPL | c.551G>A p.R184H (on ENST00000273179 / NM_001008392.2; = p.R173H on NM_005808.3) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.571); catalogued as rs370003443; called by muse, mutect2, varscan2
- CTNNA2 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.124); catalogued as rs1245962200, COSV63557850; called by muse, mutect2, varscan2
- CUX1 | c.1282G>C p.A428P | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs782489323, COSV52895909; called by muse, mutect2, varscan2
- CYB5D2 | c.41C>A p.A14D | Missense Mutation (SNP) | VAF 93/115 reads (81%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV56800734; called by muse, mutect2, varscan2
- CYP11B2 | c.1321G>A p.V441M | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs1163736521, COSV59995469; called by muse, mutect2, varscan2
- CYP2D6 | c.1162C>T p.R388C | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.695); catalogued as rs146271511; called by muse, mutect2, varscan2
- CYP4F11 | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.123); catalogued as rs1169183019, COSV56126449; called by muse, mutect2
- DAAM2 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as COSV51308403; called by muse, mutect2, varscan2
- DAPK2 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs553988389, COSV56044785; called by muse, mutect2, varscan2
- DCAF5 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs762588657, COSV58459648; called by muse, mutect2, varscan2
- DCSTAMP | c.754G>T p.V252F | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as COSV52577134; called by muse, mutect2, varscan2
- DCTN1 | c.626del p.P209Rfs*12 | Frame Shift Del (DEL) | VAF 17/59 reads (29%) | catalogued as COSV100720951; called by mutect2, pindel, varscan2
- DCTN2 | c.452C>T p.A151V (on ENST00000548249 / NM_001261413.2; = p.A156V on NM_006400.4) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.227); catalogued as COSV63073878; called by muse, mutect2, varscan2
- DDX11 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as COSV52502349; called by muse, mutect2, varscan2
- DDX18 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 78/181 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.333); catalogued as rs533216355, COSV54306128; called by muse, mutect2, varscan2
- DDX47 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs751210016, COSV61911375; called by muse, mutect2, varscan2
- DENND2C | c.2534G>A p.R845H (on ENST00000393274 / NM_001256404.2; = p.R788H on NM_198459.4) | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs566142081, COSV67920049; called by muse, mutect2, varscan2
- DENND5B | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0.065); catalogued as rs1188995096, COSV60901618; called by muse, mutect2, varscan2
- DENND6A | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as rs750447727, COSV60768233; called by muse, mutect2, varscan2
- DEPDC5 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 134/307 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56694894; called by muse, mutect2, varscan2
- DIRAS1 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV60215409; called by muse, mutect2, varscan2
- DIS3L2 | c.2350G>A p.V784M | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs754474723, COSV56051944; called by muse, mutect2, varscan2
- DLC1 | c.3170C>T p.A1057V (on ENST00000276297 / NM_001348081.2; = p.A620V on NM_006094.5) | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.621); catalogued as COSV52298290; called by muse, mutect2, varscan2
- DNAAF3 | c.757C>T p.R253W (on ENST00000524407 / NM_001256715.2; = p.R300W on NM_178837.4) | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs1281473331, COSV61276372; called by muse, mutect2, varscan2
- DNAJC1 | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747599230, COSV65410231; called by muse, mutect2, varscan2
- DNAJC10 | c.1911del p.P639Qfs*22 | Frame Shift Del (DEL) | VAF 7/18 reads (39%) | catalogued as rs1283431287; called by mutect2, pindel
- DOCK1 | c.4888C>G p.R1630G | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV54738728, COSV99732387; called by muse, mutect2
- DOCK7 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757667036, COSV52001724; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOP1A | c.7171C>T p.R2391C | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs1024056692, COSV52283380; called by muse, mutect2, varscan2
- DPH2 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs750812731, COSV99356632; called by muse, mutect2
- DSC2 | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs774641579, COSV51862960; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSCAML1 | c.6137del p.P2046Qfs*45 (on ENST00000321322; = p.P1986Qfs*45 on NM_020693.4) | Frame Shift Del (DEL) | VAF 4/9 reads (44%) | catalogued as rs1345834453; called by mutect2, varscan2
- DST | c.10985G>A p.R3662H (on ENST00000361203 / NM_001374722.1; = p.R1250H on NM_015548.5) | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.245); catalogued as rs755261768, COSV55007611; called by muse, mutect2, varscan2
- DSTYK | c.1838G>A p.G613D | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.346); catalogued as rs1361367833, COSV65686090; called by muse, mutect2, varscan2
- DTNA | c.1555C>T p.R519W | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371363393, COSV52011927; called by muse, mutect2, varscan2
- DUSP22 | c.352G>A p.V118M | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758237999, COSV60525634, COSV60527944; called by muse, mutect2, varscan2
- DVL1 | c.857G>A p.G286D | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376597258; called by muse, mutect2, varscan2
- EEF1A2 | c.714dup p.T239Hfs*50 | Frame Shift Ins (INS) | VAF 17/75 reads (23%) | catalogued as rs1290330632; called by mutect2, pindel, varscan2
- EHMT2 | c.1861G>A p.V621M | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as rs776943251, COSV64995378; called by muse, mutect2, varscan2
- EIF2D | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as rs199944579; called by muse, mutect2, varscan2
- EIF3A | c.3181C>T p.R1061C | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); catalogued as rs1360285001, COSV64960949; called by muse, mutect2, varscan2
- EIF3E | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 60/204 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as COSV55202314; called by muse, varscan2
- EIF4A2 | c.193_195del p.I65del | In Frame Del (DEL) | VAF 18/62 reads (29%) | catalogued as rs755185062; called by pindel, varscan2
- EIF4G1 | c.2090C>T p.A697V (on ENST00000346169 / NM_198241.3; = p.A502V on NM_004953.5) | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.041); catalogued as COSV59990216; called by muse, mutect2, varscan2
- ELL3 | c.1111C>T p.R371C | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as rs751833360, COSV55855456; called by muse, mutect2, varscan2
- ELOA2 | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.99); catalogued as COSV55296949, COSV55299257; called by muse, mutect2, varscan2
- ENG | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs751787590, COSV61226477; called by muse, mutect2, varscan2
- EPHA5 | c.2558G>A p.R853Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs772452750, COSV56639254; called by muse, mutect2, varscan2
- EPN1 | c.115C>A p.L39I | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV50036581; called by muse, mutect2, varscan2
- EPSTI1 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs1466356190, COSV58044846; called by muse, mutect2, varscan2
- ERBB3 | c.1703C>T p.S568L | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs748595358, COSV57250456; called by muse, mutect2, varscan2
- EVA1B | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.415); catalogued as COSV54633915; called by muse, mutect2, varscan2
- EVL | c.368G>A p.R123H (on ENST00000402714 / NM_001330221.2; = p.R125H on NM_016337.3) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs770493838, COSV67374775; called by muse, mutect2, varscan2
- EXOC1 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 53/200 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as COSV62119831; called by muse, mutect2, varscan2
- EYA1 | c.1703C>T p.A568V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as rs765493132, COSV58160092; called by muse, mutect2
- FAM160B1 | c.1514C>A p.P505H | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV100985625, COSV65087798; called by muse, varscan2
- FAM160B2 | c.1813C>T p.R605* | Nonsense Mutation (SNP) | VAF 14/49 reads (29%) | catalogued as rs756579712, COSV57157966; called by muse, mutect2, varscan2
- FAM214B | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs767921532, COSV59715636; called by muse, mutect2, varscan2
- FASN | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as rs533081221, COSV60752715; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAT2 | c.8182C>T p.R2728W | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs201629483; called by muse, mutect2, varscan2
- FAT3 | c.1298G>A p.R433Q | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs200065507; called by muse, mutect2, varscan2
- FBXL19 | c.806C>A p.A269D | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV57941695; called by muse, mutect2, varscan2
- FBXW5 | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs373092014; called by muse, mutect2, varscan2
- FEM1A | c.1847C>T p.T616M | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.207); catalogued as COSV54163408; called by muse, mutect2, varscan2
- FGF14 | c.152C>T p.T51M | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV65940132; called by muse, mutect2, varscan2
- FNDC4 | c.30del p.S11Afs*17 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs771665646, COSV99253963; called by mutect2, varscan2
- FNIP2 | c.2089C>T p.R697W | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as rs375103955; called by muse, mutect2, varscan2
- FOLH1 | c.1309-1G>A p.X437_splice | Splice Site (SNP) | VAF 75/240 reads (31%) | catalogued as COSV57047700; called by muse, mutect2, varscan2
- FOSB | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62278549; called by muse, mutect2, varscan2
- FOXP4 | c.1728C>T p.A576= (on ENST00000307972 / NM_001012426.1; = p.A563= on NM_138457.3) | Splice Region (SNP) | VAF 23/46 reads (50%) | catalogued as rs184617817; called by muse, mutect2, varscan2
- FRY | c.7057C>T p.R2353C | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs754836335, COSV66568132; called by muse, mutect2, varscan2
- FZD2 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867681109, COSV59528501; called by muse, mutect2, varscan2
- GABRD | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.408); catalogued as rs759924857, COSV66080305; called by muse, mutect2, varscan2
- GALE | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.4); catalogued as rs775614393, COSV52525561; called by muse, mutect2, varscan2
- GATA2 | c.631G>A p.V211I | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62003815; called by muse, mutect2, varscan2
- GBP3 | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs1376560310, COSV52518006; called by muse, mutect2, varscan2
- GFAP | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs773456179, COSV53649915; called by muse, mutect2, varscan2
- GHSR | c.964C>A p.L322M | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53838369; called by muse, mutect2, varscan2
- GLDC | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs757620314, COSV58678697, COSV58683145; called by muse, mutect2, varscan2
- GLE1 | c.2065G>A p.G689S | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV100012780; called by muse, mutect2
- GLRA1 | c.1149G>T p.Q383H (on ENST00000455880 / NM_001146040.2; = p.Q375H on NM_000171.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.409); catalogued as COSV51010072; called by muse, mutect2, varscan2
- GOLGB1 | c.2192del p.N731Mfs*23 | Frame Shift Del (DEL) | VAF 75/224 reads (33%) | catalogued as COSV61466595; called by mutect2, pindel, varscan2
- GPC2 | c.775G>A p.G259S | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.141); catalogued as rs371635224, COSV52784634; called by muse, mutect2, varscan2
- GPR182 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs746296301, COSV55625950; called by muse, mutect2, varscan2
- GPR20 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66683995; called by muse, mutect2, varscan2
- GPR3 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs888624926, COSV64994502; called by muse, mutect2, varscan2
- GPRIN1 | c.1602G>T p.K534N | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.069); catalogued as COSV56137021; called by muse, mutect2, varscan2
- GRAMD4 | c.1609G>A p.V537M | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV63029858; called by muse, mutect2, varscan2
- GRIK3 | c.2278A>G p.I760V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV66138029; called by muse, mutect2, varscan2
- GRIP2 | c.3367G>A p.A1123T (on ENST00000619221; = p.A1026T on NM_001080423.4) | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as rs781001244, COSV99817628; called by muse, mutect2, varscan2
- GRM5 | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs201050787, COSV59599629; called by muse, mutect2, varscan2
- GXYLT1 | c.668del p.L223Yfs*11 | Frame Shift Del (DEL) | VAF 22/63 reads (35%) | catalogued as rs750293240, COSV55140417; called by mutect2, varscan2
- H2AC21 | c.222_224del p.N74del | In Frame Del (DEL) | VAF 32/207 reads (15%) | catalogued as rs782193634; called by pindel, varscan2
- H2BC5 | c.364T>C p.Y122H | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.057); catalogued as COSV56800573; called by muse, mutect2, varscan2
- H3C4 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); catalogued as rs1206226675, COSV61911781; called by muse, mutect2, varscan2
- HAS1 | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs1416323528, COSV55789033; called by muse, mutect2, varscan2
- HCRTR2 | c.32del p.P11Lfs*11 | Frame Shift Del (DEL) | VAF 13/55 reads (24%) | catalogued as rs755844571, COSV63794110; called by mutect2, varscan2
- HDHD5 | c.487G>A p.A163T (on ENST00000336737 / NM_033070.3; = p.A133T on NM_017829.5) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.141); catalogued as rs749947487, COSV50085048; called by muse, mutect2, varscan2
- HEATR5B | c.3932G>A p.R1311Q | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as rs767921597, COSV51851610; called by muse, mutect2, varscan2
- HECTD4 | c.13057G>A p.D4353N | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs1360688634, COSV66389781; called by muse, mutect2, varscan2
- HECW1 | c.4381C>T p.R1461C | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs929423946, COSV67838087; called by muse, mutect2, varscan2
- HELZ2 | c.3746G>A p.R1249H (on ENST00000467148 / NM_001037335.2; = p.R680H on NM_033405.3) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs768418245, COSV71295703; called by muse, mutect2, varscan2
- HESX1 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs763261432, COSV55843292; called by muse, mutect2, varscan2
- HIC2 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs756084507, COSV68041965; called by muse, mutect2, varscan2
- HOOK1 | c.2126G>T p.R709L | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64618383; called by muse, mutect2, varscan2
- HTR1B | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as COSV64051336; called by muse, mutect2, varscan2
- HTRA4 | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs777434731, COSV56758359; called by muse, mutect2, varscan2
- ICA1 | c.611del p.N204Tfs*5 | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | catalogued as rs747841314; called by mutect2, varscan2
- ICAM5 | c.1547C>T p.A516V | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.851); catalogued as COSV55746777; called by muse, mutect2, varscan2
- IGF1 | c.133T>G p.S45A | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100191334; called by muse, mutect2, varscan2
- IGF2R | c.3949del p.D1317Tfs*27 | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | catalogued as rs760021495; called by mutect2, varscan2
- IGF2R | c.4916_4918del p.S1639del | In Frame Del (DEL) | VAF 8/31 reads (26%) | catalogued as rs777541035; called by mutect2, pindel
- IGSF22 | c.1252C>A p.P418T | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as COSV60032796; called by muse, mutect2, varscan2
- IHH | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55392992; called by muse, mutect2, varscan2
- INF2 | c.237G>T p.E79D | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV57979217, COSV57986944; called by muse, mutect2, varscan2
- INPP5J | c.1819C>T p.R607C (on ENST00000331075 / NM_001284285.2; = p.R239C on NM_001002837.2) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369582455; called by muse, mutect2, varscan2
- INPP5K | c.1080G>A p.W360* | Nonsense Mutation (SNP) | VAF 5/29 reads (17%) | catalogued as COSV100233908; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- INSRR | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs200875065, COSV63872081; called by muse, mutect2, varscan2
- INTS1 | c.6442G>A p.A2148T | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1270736403, COSV101248290; called by muse, mutect2, varscan2
- IPO13 | c.455C>G p.A152G | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.109); catalogued as COSV64894078; called by muse, mutect2, varscan2
- ITGA5 | c.2134-1G>T p.X712_splice | Splice Site (SNP) | VAF 34/77 reads (44%) | catalogued as COSV53215492, COSV53216798; called by muse, mutect2, varscan2
- ITM2A | c.338A>G p.E113G | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64810776; called by muse, mutect2, varscan2
- JAG2 | c.2220del p.G741Afs*21 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | catalogued as rs1555369773; called by mutect2, pindel
- KALRN | c.341C>T p.T114M | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.753); catalogued as rs750456225, COSV53756036; called by muse, mutect2, varscan2
- KCNA10 | c.791A>G p.Q264R | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV63904507; called by muse, mutect2
- KCNA6 | c.487C>T p.L163F | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.53); catalogued as COSV54974693; called by muse, mutect2, varscan2
- KCNAB1 | c.214C>A p.L72I | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.039); catalogued as COSV67484394, COSV67485247; called by muse, mutect2, varscan2
- KCNC1 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV99789698; called by muse, mutect2, varscan2
- KCNH4 | c.1508G>A p.R503H | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.6); PolyPhen benign (0.014); catalogued as rs943923559, COSV52916520; called by muse, mutect2, varscan2
- KCNS3 | c.258del p.K87Sfs*54 | Frame Shift Del (DEL) | VAF 29/102 reads (28%) | catalogued as COSV100410961; called by mutect2, pindel, varscan2
- KCTD19 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV58572145, COSV58572323; called by muse, mutect2, varscan2
- KCTD21 | c.365C>T p.T122M | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs370613583, COSV60740668; called by muse, mutect2, varscan2
- KDM7A | c.1159A>G p.R387G | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50090751; called by muse, mutect2, varscan2
- KIAA0232 | c.730C>T p.H244Y | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV56924426; called by muse, mutect2, varscan2
- KIAA0319 | c.2659C>T p.R887* | Nonsense Mutation (SNP) | VAF 22/58 reads (38%) | catalogued as rs754440682, COSV100985784, COSV65496780; called by muse, mutect2, varscan2
- KIAA0319L | c.3056G>A p.R1019Q | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.096); catalogued as rs767449634, COSV57844239; called by muse, mutect2, varscan2
- KIAA1109 | c.14680del p.S4894Vfs*36 | Frame Shift Del (DEL) | VAF 18/49 reads (37%) | catalogued as rs746889467; called by mutect2, pindel, varscan2
- KIF13B | c.3427G>A p.A1143T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as rs766406923, COSV72954322; called by muse, mutect2, varscan2
- KIF18B | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 37/47 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV59272281; called by muse, mutect2, varscan2
- KLC4 | c.1629+1del | Frame Shift Del (DEL) | VAF 60/162 reads (37%) | catalogued as rs1244882940; called by mutect2, pindel, varscan2
- KLHDC8A | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs767633455, COSV65678601; called by muse, mutect2, varscan2
- LAMA3 | c.9815C>T p.P3272L (on ENST00000313654 / NM_198129.4; = p.P1663L on NM_000227.6) | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as COSV52533027; called by muse, mutect2, varscan2
- LDHAL6B | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs766463782, COSV55684934; called by muse, mutect2, varscan2
- LENG9 | c.1401dup p.P468Afs*7 | Frame Shift Ins (INS) | VAF 15/41 reads (37%) | catalogued as rs757537115; called by mutect2, pindel, varscan2
- LMAN2L | c.669G>A p.T223= | Splice Region (SNP) | VAF 11/34 reads (32%) | catalogued as rs751372909, COSV53841305, COSV99383410; called by muse, mutect2, varscan2
- LMF1 | c.1352G>A p.R451Q | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as rs772059919, COSV51895872; called by muse, mutect2, varscan2
- LMF2 | c.1157+2T>C p.X386_splice | Splice Site (SNP) | VAF 21/41 reads (51%) | catalogued as COSV53316852; called by muse, mutect2, varscan2
- LRIF1 | c.2252T>C p.V751A | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100870918; called by muse, mutect2, varscan2
- LRRC17 | c.1272del p.K424Nfs*12 | Frame Shift Del (DEL) | VAF 22/58 reads (38%) | catalogued as rs745668314; called by mutect2, varscan2
- LY6G6C | c.222G>T p.E74D | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.146); catalogued as COSV65404172; called by muse, mutect2, varscan2
- LZTS2 | c.210G>T p.Q70H | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV64651366; called by muse, mutect2, varscan2
- MAD1L1 | c.2012C>T p.S671L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.348); catalogued as rs577277453, COSV56231544; called by muse, mutect2, varscan2
- MAGEA10 | c.206G>A p.S69N | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); catalogued as COSV54883582; called by muse, mutect2, varscan2
- MAGEL2 | c.2245C>T p.R749C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV58566571; called by muse, mutect2, varscan2
- MAN2A1 | c.3060G>A p.M1020I | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as rs1005344140, COSV54850088; called by muse, mutect2, varscan2
- MAN2A2 | c.260C>A p.A87D | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.25); catalogued as COSV100847985; called by muse, mutect2, varscan2
- MAP3K12 | c.1811G>A p.R604H | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.375); catalogued as rs754240127, COSV57231852; called by muse, mutect2, varscan2
- MAP3K13 | c.1774C>T p.R592* | Nonsense Mutation (SNP) | VAF 35/108 reads (32%) | catalogued as COSV53986537; called by muse, mutect2, varscan2
- MAPK15 | c.191T>C p.L64P | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62027924; called by muse, mutect2, varscan2
- MARF1 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs201651611; called by muse, mutect2, varscan2
- MARS1 | c.1274T>C p.I425T | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV56253729; called by muse, mutect2, varscan2
- MATN1 | c.85del p.Q29Sfs*32 | Frame Shift Del (DEL) | VAF 20/69 reads (29%) | catalogued as rs1419789464; called by mutect2, pindel, varscan2
- MATN4 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 15/43 reads (35%) | PolyPhen possibly damaging (0.773); catalogued as rs2233092, COSV59213229; called by muse, mutect2, varscan2
- MBTPS1 | c.721C>T p.R241* | Nonsense Mutation (SNP) | VAF 24/53 reads (45%) | catalogued as rs1567496535, COSV58570201; called by muse, varscan2
- MCM3AP | c.3734+1G>A p.X1245_splice | Splice Site (SNP) | VAF 10/39 reads (26%) | catalogued as COSV52438464; called by muse, mutect2, varscan2
- MCOLN1 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs762783827, COSV51174680; called by muse, mutect2, varscan2
- MDFIC | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57563117; called by muse, mutect2, varscan2
- MDN1 | c.5029C>T p.R1677* | Nonsense Mutation (SNP) | VAF 32/90 reads (36%) | catalogued as rs763036622, COSV101021800; called by muse, varscan2
- MED13 | c.3452G>A p.R1151H | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs147399023, COSV67262896; called by muse, mutect2, varscan2
- MED13L | c.746del p.K249Rfs*23 | Frame Shift Del (DEL) | VAF 108/348 reads (31%) | catalogued as rs1566014158; called by pindel, varscan2
- MEFV | c.2110G>A p.V704I | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs104895096, CM012154, COSV54820562; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MEI1 | c.3338T>C p.L1113P | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100300303; called by muse, mutect2
- MEX3B | c.896C>G p.S299C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs1346574800, COSV61663162; called by muse, mutect2, varscan2
- MFN2 | c.306del p.F102Lfs*11 | Frame Shift Del (DEL) | VAF 42/124 reads (34%) | catalogued as rs777012596; called by mutect2, pindel, varscan2
- MFSD5 | c.904G>A p.A302T | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.117); catalogued as rs376685034; called by muse, mutect2, varscan2
- MGAT1 | c.1166C>T p.T389M | Missense Mutation (SNP) | VAF 14/35 reads (40%) | PolyPhen possibly damaging (0.734); catalogued as rs368412689; called by muse, mutect2, varscan2
- MIA | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.368); catalogued as COSV54571173; called by muse, mutect2, varscan2
- MICALL2 | c.1987C>T p.R663C | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs774448634, COSV52514494; called by muse, varscan2
- MINAR1 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs746811582, COSV59582046; called by muse, mutect2, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MITF | c.1049C>T p.S350F (on ENST00000448226 / NM_006722.3; = p.S250F on NM_000248.4) | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58830741; called by muse, mutect2, varscan2
- MMP28 | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as rs1312239488; called by muse, mutect2
- MMP8 | c.210del p.F70Lfs*3 | Frame Shift Del (DEL) | VAF 48/146 reads (33%) | catalogued as COSV52634246; called by mutect2, pindel, varscan2
- MMP9 | c.1792C>A p.P598T | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63433935; called by muse, mutect2, varscan2
- MOG | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 71/144 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.411); catalogued as COSV65305937; called by muse, mutect2, varscan2
- MRPL2 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs150400847; called by muse, mutect2, varscan2
- MRPL37 | c.349G>A p.V117I | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.61); catalogued as COSV60321418; called by muse, mutect2, varscan2
- MRPL50 | c.450dup p.N151Qfs*24 | Frame Shift Ins (INS) | VAF 27/84 reads (32%) | catalogued as rs755588721; called by mutect2, pindel, varscan2
- MSH2 | c.1552_1553del p.Q518Vfs*10 | Frame Shift Del (DEL) | VAF 36/77 reads (47%) | catalogued as rs63749930; called by pindel, varscan2
- MTG2 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs915870996, COSV63693603; called by muse, mutect2, varscan2
- MUC4 | c.15872-1G>A p.X5291_splice (on ENST00000463781 / NM_018406.7; = p.X1055_splice on NM_004532.6) | Splice Site (SNP) | VAF 5/19 reads (26%) | catalogued as rs778550865, COSV100206338; called by muse, mutect2, varscan2
- MVK | c.1006G>A p.G336S | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104895358, CM068195, COSV57331635; ClinVar: not provided; called by muse, mutect2, varscan2
- MYBBP1A | c.2674G>A p.D892N | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as rs562871359, COSV99626855; called by muse, mutect2, varscan2
- MYBPC1 | c.2540A>G p.Q847R (on ENST00000550270 / NM_206820.2; = p.Q854R on NM_002465.4) | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as COSV62252279; called by muse, mutect2, varscan2
- MYH9 | c.2159+2T>C p.X720_splice | Splice Site (SNP) | VAF 8/30 reads (27%) | catalogued as COSV99339755; called by muse, mutect2, varscan2
- MYO7A | c.2024G>A p.R675H | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs782743967, COSV68684287; called by muse, mutect2, varscan2
- NAALAD2 | c.857C>A p.P286H | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58960025; called by muse, mutect2, varscan2
- NBL1 | c.517del p.H173Tfs*37 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs1382618264; called by mutect2, pindel
- NCK2 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs750135733, COSV51890312; called by muse, mutect2, varscan2
- NDUFA10 | c.655C>T p.Q219* | Nonsense Mutation (SNP) | VAF 20/44 reads (45%) | catalogued as rs866538036, COSV99401727; called by muse, mutect2, varscan2
- NDUFS3 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs78121716, COSV55454156; called by muse, mutect2, varscan2
- NECAB3 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs746352570, COSV55775551; called by muse, mutect2, varscan2
- NFKBIB | c.326C>T p.T109M | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.322); catalogued as rs139372587; called by muse, mutect2, varscan2
- NHLRC2 | c.1816G>A p.V606M | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.326); catalogued as rs757540255, COSV65174661; called by muse, mutect2, varscan2
- NLRC5 | c.1986G>T p.E662D | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV52653164; called by muse, mutect2, varscan2
- NOB1 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs373158111; called by muse, varscan2
- NOS3 | c.3379G>A p.V1127M | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs1238557283, COSV52488356; called by muse, mutect2, varscan2
- NPFFR2 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as COSV58148486; called by muse, mutect2, varscan2
- NRBP1 | c.274G>A p.V92I | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV51993837; called by muse, mutect2, varscan2
- NUFIP2 | c.103C>T p.H35Y | Missense Mutation (SNP) | VAF 70/161 reads (43%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as COSV56602889; called by muse, mutect2, varscan2
- NYAP2 | c.968C>A p.P323H | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56002352; called by muse, mutect2, varscan2
- OBSCN | c.7484C>T p.A2495V | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.492); catalogued as COSV52761426; called by muse, mutect2, varscan2
- OLAH | c.294del p.F98Lfs*15 (on ENST00000378228 / NM_001039702.3; = p.F151Lfs*15 on NM_018324.3) | Frame Shift Del (DEL) | VAF 53/147 reads (36%) | catalogued as rs1452760362; called by mutect2, pindel, varscan2
- OLFM1 | c.1277A>G p.Y426C (on ENST00000371793 / NM_001282611.2; = p.Y408C on NM_014279.5) | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53277609; called by muse, mutect2, varscan2
- ONECUT2 | c.449C>T p.T150M | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV72203296; called by muse, mutect2, varscan2
- ONECUT3 | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV101210696; called by muse, varscan2
- OR10C1 | c.233C>T p.T78M (on ENST00000622521; = p.T76M on NM_013941.3) | Missense Mutation (SNP) | VAF 7/158 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.37); catalogued as COSV101010795; called by muse, mutect2
- OR10H1 | c.43G>A p.V15I | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV58471159; called by muse, mutect2, varscan2
- OR11L1 | c.186C>G p.F62L | Missense Mutation (SNP) | VAF 56/116 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.666); catalogued as COSV63313751, COSV63314072, COSV63315360; called by muse, mutect2, varscan2
- OR2T10 | c.841C>A p.L281I | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.1); catalogued as COSV57896583; called by muse, mutect2, varscan2
- OR5D16 | c.121G>T p.V41L | Missense Mutation (SNP) | VAF 79/223 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV99058713; called by muse, mutect2, varscan2
- OR5T2 | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs761907002, COSV57588609; called by muse, mutect2, varscan2
- P2RY10 | c.931G>T p.E311* | Nonsense Mutation (SNP) | VAF 11/64 reads (17%) | catalogued as COSV50680881, COSV50681309; called by muse, mutect2, varscan2
- PANX2 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.238); catalogued as COSV99348637; called by mutect2, varscan2
- PASK | c.1121C>T p.T374M | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs377122334; called by muse, mutect2, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 22/58 reads (38%) | catalogued as CM011452; called by mutect2, pindel, varscan2
- PC | c.2825G>A p.R942H | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.43); catalogued as rs370436212; called by muse, mutect2, varscan2
- PCDH9 | c.3148C>T p.R1050C (on ENST00000377865 / NM_203487.3; = p.R1016C on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs368726260, COSV100117873; called by muse, mutect2
- PCDHA10 | c.1318G>A p.V440M | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.378); catalogued as COSV56491640; called by muse, mutect2, varscan2
- PCDHA3 | c.2107G>A p.A703T | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV63540376; called by muse, mutect2, varscan2
- PCDHB1 | c.1487del p.N496Tfs*12 | Frame Shift Del (DEL) | VAF 21/69 reads (30%) | catalogued as rs782781242; called by mutect2, pindel, varscan2
- PCDHGA2 | c.769G>A p.V257M | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.3); catalogued as rs1166937901, COSV53927160; called by muse, mutect2, varscan2
- PCDHGB7 | c.1663C>T p.R555C | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs781128524, COSV53927180; called by muse, mutect2, varscan2
- PCLO | c.15422C>T p.T5141M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV61626766; called by muse, mutect2, varscan2
- PCNT | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs147670433; called by muse, mutect2, varscan2
- PCNT | c.727C>T p.H243Y | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as COSV64026999; called by muse, mutect2, varscan2
- PCNT | c.2696G>A p.R899H | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs549172396, COSV64027004; called by muse, mutect2, varscan2
- PCYT2 | c.109G>A p.G37S | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58711072; called by muse, mutect2, varscan2
- PDCD11 | c.1771-2A>G p.X591_splice | Splice Site (SNP) | VAF 33/101 reads (33%) | catalogued as COSV63933592; called by muse, mutect2, varscan2
- PER3 | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 61/165 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs559444285, COSV62705270; called by muse, mutect2, varscan2
- PIAS4 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53678716; called by muse, mutect2, varscan2
- PIK3CG | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.183); catalogued as COSV63247367; called by muse, mutect2, varscan2
- PIK3CG | c.1573C>A p.H525N | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV63247373; called by muse, mutect2, varscan2
- PIK3R6 | c.860T>C p.F287S | Missense Mutation (SNP) | VAF 23/27 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV100266844; called by muse, mutect2, varscan2
- PIP5KL1 | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.432); catalogued as rs1216240109, COSV100304950; called by muse, mutect2, varscan2
- PIWIL1 | c.78+1G>A p.X26_splice | Splice Site (SNP) | VAF 29/72 reads (40%) | catalogued as rs766519202, COSV55345327; called by muse, mutect2, varscan2
- PKHD1L1 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs763680779, COSV65740803; called by muse, mutect2, varscan2
- PLA2G4D | c.2240G>A p.R747H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1373378653, COSV51820071; called by muse, mutect2, varscan2
- PLCL2 | c.611G>A p.R204H (on ENST00000615277 / NM_001144382.2; = p.R78H on NM_015184.5) | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1224337070, COSV67621484; called by muse, mutect2, varscan2
- PLXNA2 | c.4697A>G p.Q1566R | Missense Mutation (SNP) | VAF 54/81 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV65439637; called by muse, mutect2, varscan2
- PLXNA3 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs782701104, COSV63753716; called by muse, mutect2, varscan2
- PLXNB2 | c.4034G>A p.R1345H | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63780926; called by muse, mutect2, varscan2
- PLXND1 | c.2563G>A p.D855N | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775216644, COSV60711600; called by muse, mutect2, varscan2
- PMEL | c.1925G>A p.R642H | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs866948103, COSV59384936; called by muse, mutect2, varscan2
- PNMA8B | c.1184G>A p.R395H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV100885519; called by muse, mutect2
- PNPLA2 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.642); catalogued as rs746987189, COSV60743788; called by muse, mutect2, varscan2
- POLH | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64779196; called by muse, mutect2, varscan2
- POLQ | c.7738G>A p.A2580T | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); catalogued as rs375979324; called by mutect2, varscan2
- POLR1F | c.932dup p.K312Efs*6 | Frame Shift Ins (INS) | VAF 46/150 reads (31%) | catalogued as rs775851473; called by mutect2, varscan2
- POPDC2 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139251743, COSV99951148; called by muse, mutect2, varscan2
- POU6F2 | c.1832G>A p.R611H | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200415799; called by muse, mutect2, varscan2
- PPP6R2 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775609741, COSV53291872; called by muse, mutect2, varscan2
- PPRC1 | c.2131G>A p.V711M | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.036); catalogued as rs17847386, COSV53384455; called by muse, mutect2, varscan2
- PRAMEF17 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 76/200 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs989031993; called by muse, mutect2, varscan2
- PRDM1 | c.862A>G p.S288G | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.643); catalogued as rs1375448753, COSV64844961; called by muse, mutect2, varscan2
- PRDM10 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.994); catalogued as rs1375310612, COSV58800517; called by muse, mutect2, varscan2
- PRDM14 | c.1598A>T p.D533V | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99400484; called by muse, mutect2, varscan2
- PRDX2 | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.376); catalogued as rs764907738, COSV56877653; called by muse, mutect2, varscan2
- PRKCI | c.826dup p.T276Nfs*16 | Frame Shift Ins (INS) | VAF 52/171 reads (30%) | catalogued as rs753143066; called by mutect2, varscan2
- PRKCQ | c.1954C>T p.R652W | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs1179560313, COSV54121349, COSV99578040; called by muse, mutect2
- PRKD2 | c.1513C>T p.R505C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs1448737424, COSV52185452; called by muse, mutect2
- PROKR1 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs771784209, COSV58137160; called by muse, varscan2
- PROSER3 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.49); PolyPhen benign (0.078); catalogued as rs752077583, COSV56553075; called by muse, mutect2, varscan2
- PRR14 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.381); catalogued as rs1438275056, COSV54911369; called by muse, mutect2, varscan2
- PTGFRN | c.1661C>T p.A554V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs972406874, COSV67798189; called by muse, mutect2, varscan2
- PXDN | c.3337G>A p.G1113S | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1366824154, COSV53231039; called by muse, mutect2, varscan2
- PXDNL | c.3251C>T p.A1084V | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373683927, COSV62484789; called by muse, mutect2, varscan2
- RAB11A | c.214C>T p.R72* | Nonsense Mutation (SNP) | VAF 52/120 reads (43%) | catalogued as COSV56041561; called by muse, mutect2, varscan2
- RAF1 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52577036; called by muse, mutect2, varscan2
- RAG1 | c.2209C>T p.R737C | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs760816389, COSV100201137; called by muse, mutect2, varscan2
- RANBP10 | c.277A>G p.T93A | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.222); catalogued as COSV100449471; called by muse, mutect2, varscan2
- RAP1GAP | c.1895C>A p.P632H | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.216); catalogued as COSV51571302; called by muse, mutect2, varscan2
- RAP1GAP | c.1391C>T p.A464V | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as rs201567525, COSV51571341; called by muse, mutect2, varscan2
- RASA1 | c.2513del p.N838Mfs*4 | Frame Shift Del (DEL) | VAF 48/143 reads (34%) | catalogued as rs1561325048; called by mutect2, pindel, varscan2
- RASGRF1 | c.2840G>A p.R947H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.3); catalogued as rs770002588, COSV67249738, COSV67250135; called by muse, mutect2, varscan2
- RASGRF1 | c.766G>A p.V256M | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs770085797, COSV69178004; called by muse, mutect2, varscan2
- RELCH | c.3017C>T p.P1006L | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764754428, COSV56884223; called by muse, mutect2, varscan2
- RFT1 | c.667G>T p.D223Y | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV56248566; called by muse, mutect2, varscan2
- RFTN1 | c.1147G>A p.G383S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61918077; called by muse, mutect2
- RHBG | c.346G>A p.G116S | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs774514973, COSV54803104; called by muse, mutect2, varscan2
- RHPN1 | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs894947144, COSV56645949; called by muse, mutect2, varscan2
- RING1 | c.517del p.E173Kfs*14 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs761874510; called by mutect2, pindel, varscan2
- RIPK4 | c.1565C>T p.P522L (on ENST00000352483; = p.P474L on NM_020639.3) | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs970090763, COSV60186557; called by muse, mutect2, varscan2
- RMC1 | c.1747C>T p.R583W | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs772715965, COSV52571354; called by muse, mutect2, varscan2
- RNF43 | c.1310G>A p.R437Q | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs140873038; called by muse, mutect2, varscan2
- ROBO2 | c.3233del p.P1078Qfs*95 | Frame Shift Del (DEL) | VAF 26/92 reads (28%) | catalogued as rs745519558, COSV100168583; called by mutect2, varscan2
- RP1L1 | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs370720560; called by muse, mutect2, varscan2
- RPL3 | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.833); catalogued as rs1276622874; called by muse, mutect2
- RPS6KA2 | c.2186C>T p.T729M | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs781336018, COSV55818789; called by muse, mutect2
- RPS6KA5 | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs376247617; called by muse, mutect2, varscan2
- RPTOR | c.2861C>T p.T954M | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.057); catalogued as rs150835528; called by muse, mutect2, varscan2
- RPUSD3 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs377371328; called by muse, mutect2, varscan2
- RPUSD4 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.053); catalogued as rs1477711924, COSV53599061; called by muse, mutect2, varscan2
- RRP15 | c.740C>T p.T247M | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as rs776110356, COSV65117655; called by muse, mutect2, varscan2
- RUVBL1 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.476); catalogued as rs1378839372, COSV59475597; called by muse, mutect2, varscan2
- RWDD2B | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as rs765123748, COSV54501354; called by muse, mutect2, varscan2
- RYR1 | c.9724G>A p.D3242N | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.552); catalogued as rs1231911930, COSV62094217; called by muse, mutect2, varscan2
- RYR2 | c.3515C>T p.T1172I | Missense Mutation (SNP) | VAF 58/223 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.879); catalogued as rs768755342, COSV63677285, COSV63712043; called by muse, mutect2, varscan2
- SALL2 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs538590182, COSV58102691; called by muse, mutect2, varscan2
- SCAMP2 | c.342T>C p.H114= | Splice Region (SNP) | VAF 12/34 reads (35%) | catalogued as COSV51510794; called by muse, mutect2, varscan2
- SCMH1 | c.286G>A p.D96N (on ENST00000326197 / NM_001031694.2; = p.D49N on NM_012236.4) | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100402129; called by muse, mutect2, varscan2
- SCN5A | c.6023C>T p.P2008L (on ENST00000333535 / NM_198056.3; = p.P2007L on NM_000335.5) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs750070697, COSV61120929; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SDF2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.057); catalogued as COSV55931636; called by muse, mutect2, varscan2
- SELENOP | c.181C>A p.L61M | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV101539876; called by muse, mutect2, varscan2
- SEMG1 | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 108/263 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV54872416; called by muse, mutect2, varscan2
- SEPTIN4 | c.1043G>A p.G348D | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57895629; called by muse, mutect2, varscan2
- SET | c.229C>T p.R77C (on ENST00000372692 / NM_001374326.1; = p.R64C on NM_003011.4) | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.444); catalogued as COSV59001542; called by muse, mutect2, varscan2
- SET | c.572G>A p.S191N (on ENST00000372692 / NM_001374326.1; = p.S178N on NM_003011.4) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as COSV59002024; called by muse, mutect2, varscan2
- SETBP1 | c.4399G>A p.D1467N | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.964); catalogued as COSV56318299; called by muse, mutect2, varscan2
- SEZ6L | c.809C>T p.T270M | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371478865; called by muse, varscan2
- SF3A1 | c.1414C>T p.R472W | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53167577; called by muse, mutect2, varscan2
- SGO2 | c.1929del p.G644Vfs*18 | Frame Shift Del (DEL) | VAF 53/174 reads (30%) | catalogued as rs1260834379; called by mutect2, pindel, varscan2
- SGTA | c.223C>A p.L75M | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV55593651; called by muse, mutect2, varscan2
- SH2B1 | c.427A>G p.T143A | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (1); PolyPhen possibly damaging (0.482); catalogued as rs755239754, COSV100451232; called by mutect2, varscan2
- SHOC1 | c.1582C>T p.R528* | Nonsense Mutation (SNP) | VAF 43/90 reads (48%) | catalogued as rs1004968910, COSV59499699; called by muse, mutect2, varscan2
- SIAE | c.1367T>C p.M456T | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as rs201702369; called by muse, mutect2, varscan2
- SIM1 | c.852G>A p.L284= | Splice Region (SNP) | VAF 18/39 reads (46%) | catalogued as COSV53490753; called by muse, mutect2, varscan2
- SLC11A1 | c.597del p.F199Lfs*5 | Frame Shift Del (DEL) | VAF 109/300 reads (36%) | catalogued as rs1362974823; called by mutect2, pindel, varscan2
- SLC20A2 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1366061951, COSV60602735; called by muse, mutect2, varscan2
- SLC22A23 | c.1327G>A p.G443R | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778961106, COSV66677131; called by muse, mutect2, varscan2
- SLC25A47 | c.185C>T p.T62M | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.426); catalogued as rs202229264, COSV64161748; called by muse, mutect2, varscan2
- SLC27A5 | c.70G>A p.V24M | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV54018899; called by muse, mutect2, varscan2
- SLC4A1AP | c.647G>T p.R216M | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58134345, COSV58136375; called by muse, mutect2, varscan2
- SLC66A1 | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs143243971, COSV64320854; called by muse, varscan2
- SLC8A2 | c.2680G>A p.A894T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as COSV52639030; called by muse, mutect2
- SLC8B1 | c.1304C>T p.A435V | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as rs748038619, COSV52527222; called by muse, mutect2, varscan2
- SLC9B1 | c.525G>T p.Q175H | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV56468967; called by muse, mutect2
- SLTM | c.2548C>T p.R850* | Nonsense Mutation (SNP) | VAF 9/141 reads (6%) | catalogued as COSV100998859; called by muse, mutect2
- SMARCA4 | c.3557C>T p.A1186V | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV60788639, COSV60811013; called by muse, mutect2, varscan2
- SMG1 | c.6908C>A p.S2303Y | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV67170606, COSV67170729; called by muse, mutect2, varscan2
- SMG5 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62434800; called by muse, mutect2, varscan2
- SNRNP25 | c.239G>A p.R80H (on ENST00000383018; = p.R71H on NM_024571.4) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1218771951, COSV51954704; called by muse, mutect2, varscan2
- SOHLH2 | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV65900906; called by muse, mutect2, varscan2
- SON | c.5585G>A p.R1862H | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs758958383, COSV51655168; called by muse, mutect2, varscan2
- SOX9 | c.916del p.V306Cfs*77 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | catalogued as rs1297203260; called by mutect2, pindel, varscan2
- SPAG17 | c.4821dup p.L1608Ifs*4 | Frame Shift Ins (INS) | VAF 42/141 reads (30%) | catalogued as rs1342911544; called by mutect2, varscan2
- SPATA31D1 | c.4445G>A p.G1482D | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.361); catalogued as COSV61194521; called by muse, mutect2, varscan2
- SPEN | c.1658G>C p.G553A | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65360305; called by muse, mutect2, varscan2
- SPG21 | c.173T>G p.V58G | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV99200205; called by muse, mutect2, varscan2
- SPIRE2 | c.1475C>T p.A492V | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs746193823, COSV65555064; called by muse, mutect2, varscan2
- SPTA1 | c.4689C>A p.N1563K | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.02); catalogued as rs752190913, COSV63751420; called by muse, mutect2, varscan2
- SPTBN2 | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1309547051, COSV59449413; called by muse, varscan2
- SRPX | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 57/68 reads (84%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as rs375318852, COSV59437935; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SSH1 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs368822154; called by muse, mutect2, varscan2
- STAC3 | c.114G>T p.K38N | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV60413997; called by muse, mutect2, varscan2
- STAM2 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs137997902; called by muse, mutect2, varscan2
- STIM1 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs555016539, COSV56153429; called by muse, mutect2, varscan2
- STS | c.1586C>T p.A529V | Missense Mutation (SNP) | VAF 19/21 reads (90%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370888998, COSV54266314; called by muse, mutect2, varscan2
- SURF4 | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs782694838, COSV64338773; called by muse, mutect2, varscan2
- SVIL | c.4077G>T p.Q1359H (on ENST00000355867 / NM_021738.3; = p.Q933H on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs776373064; called by mutect2, varscan2
- SZT2 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.445); catalogued as COSV60290043; called by muse, mutect2, varscan2
- TACC1 | c.1502G>A p.G501D | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV52522955; called by muse, mutect2, varscan2
- TAS2R10 | c.896A>G p.E299G | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV53700839; called by muse, mutect2, varscan2
- TBR1 | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV67417618; called by muse, mutect2, varscan2
- TCAF1 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs149141329; called by muse, mutect2, varscan2
- TCF4 | c.1201C>T p.R401W | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1337772395, COSV61893873; called by muse, mutect2
- TCOF1 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs373269393; called by muse, mutect2, varscan2
- TEPP | c.119C>A p.P40H | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.54); catalogued as COSV52042929; called by muse, mutect2, varscan2
- TET3 | c.2158G>A p.D720N | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as COSV59880623; called by muse, mutect2, varscan2
- TFR2 | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs958164035, COSV99774714; called by muse, mutect2, varscan2
- TGM7 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs150218635; called by muse, mutect2, varscan2
- THOC5 | c.38T>G p.V13G | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV100803652; called by muse, mutect2, varscan2
- THOC7 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1254331510, COSV55733193; called by muse, mutect2, varscan2
- TICAM1 | c.1925del p.P642Hfs*50 | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | catalogued as COSV50235787; called by mutect2, pindel, varscan2
- TINAGL1 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.896); catalogued as rs753540392, COSV54698784; called by muse, mutect2, varscan2
- TLCD4 | c.290G>A p.G97D | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64631925; called by muse, mutect2, varscan2
- TLR10 | c.2256del p.A753Hfs*28 | Frame Shift Del (DEL) | VAF 26/82 reads (32%) | catalogued as rs564674109; called by mutect2, varscan2
- TMCO6 | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 45/96 reads (47%) | catalogued as rs572885706, COSV52799473; called by muse, mutect2, varscan2
- TMEFF2 | c.1106C>T p.A369V | Missense Mutation (SNP) | VAF 99/277 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV55830811; called by muse, mutect2, varscan2
- TMEM163 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56105347; called by muse, mutect2, varscan2
- TMEM201 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0.01); catalogued as rs752313181, COSV61051216, COSV61052237; called by muse, mutect2, varscan2
- TMPRSS15 | c.2325del p.K775Nfs*58 | Frame Shift Del (DEL) | VAF 25/72 reads (35%) | catalogued as rs749950017; called by mutect2, pindel, varscan2
- TMX1 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 19/191 reads (10%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as rs369843771; called by muse, mutect2, varscan2
- TNFRSF11A | c.301G>A p.V101M | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1020903615, COSV54022728; called by muse, mutect2, varscan2
- TNRC18 | c.4615C>A p.L1539M | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as COSV68164452; called by muse, mutect2, varscan2
- TNRC6B | c.3023G>A p.R1008H (on ENST00000454349 / NM_001162501.2; = p.R955H on NM_015088.3) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs940813954, COSV57292793; called by muse, mutect2, varscan2
- TNXB | c.13050C>A p.G4350= (on ENST00000647633; = p.G4103= on NM_019105.8 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 32/89 reads (36%) | catalogued as COSV100926607; called by muse, mutect2, varscan2
- TOLLIP | c.714G>T p.Q238H | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as COSV55135905; called by muse, mutect2, varscan2
- TPR | c.6248del p.P2083Qfs*3 | Frame Shift Del (DEL) | VAF 73/269 reads (27%) | catalogued as rs1557988252; called by mutect2, pindel, varscan2
- TRAF3 | c.1517G>A p.R506H | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.166); catalogued as COSV61024565; called by muse, mutect2, varscan2
- TRAP1 | c.841G>A p.V281I | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT tolerated (0.17); PolyPhen benign (0.048); catalogued as rs757572551, COSV55915741; called by muse, mutect2, varscan2
- TRIO | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60081200; called by muse, mutect2, varscan2
- TRMT6 | c.458del p.K153Nfs*9 | Frame Shift Del (DEL) | VAF 26/50 reads (52%) | catalogued as rs780358338; called by mutect2, varscan2
- TRPM4 | c.1798G>A p.A600T | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV53261676; called by muse, mutect2, varscan2
- TSGA10IP | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs753175238, COSV73245241; called by muse, mutect2, varscan2
- TSHZ3 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs923574447, COSV53665122; called by muse, mutect2, varscan2
- TSN | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs189627724, COSV67605270; called by muse, mutect2, varscan2
- TTC39A | c.1687G>A p.E563K (on ENST00000447632 / NM_001297665.1; = p.E528K on NM_001080494.3) | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as rs755961811, COSV52957492; called by muse, mutect2, varscan2
- TTC7A | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs201734751, COSV55410061; called by muse, mutect2, varscan2
- TTN | c.76226A>G p.E25409G (on ENST00000591111; = p.E17985G on NM_003319.4) | Missense Mutation (SNP) | VAF 58/119 reads (49%) | PolyPhen probably damaging (0.997); catalogued as rs938840239, COSV59981574; called by muse, mutect2, varscan2
- TTN | c.7862C>T p.A2621V (on ENST00000591111; = p.A2575V on NM_003319.4) | Missense Mutation (SNP) | VAF 29/99 reads (29%) | PolyPhen probably damaging (0.997); catalogued as rs753441258, COSV59981613, COSV59991676; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TULP4 | c.2848C>T p.R950C | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs117337831; called by muse, mutect2, varscan2
- U2AF1L4 | c.374G>A p.R125Q (on ENST00000412391; = p.R86Q on NM_144987.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.227); catalogued as rs142741890, COSV99495514; called by muse, mutect2, varscan2
- UBQLN4 | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64148969; called by muse, mutect2, varscan2
- UNKL | c.2177G>A p.C726Y (on ENST00000389221 / NM_001372107.1; = p.C676Y on NM_001193388.4) | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99201630; called by muse, mutect2
- USH1C | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.11); catalogued as rs760703501, COSV50015240; called by muse, mutect2, varscan2
- USP13 | c.1896del p.I633* | Frame Shift Del (DEL) | VAF 23/61 reads (38%) | catalogued as rs780272979; called by mutect2, varscan2
- USP21 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV57087712; called by muse, mutect2, varscan2
- USP35 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1273026171, COSV71572701; called by muse, mutect2, varscan2
- USP36 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61751112; called by muse, mutect2, varscan2
- UTS2B | c.130del p.Y44Ifs*12 | Frame Shift Del (DEL) | VAF 56/173 reads (32%) | catalogued as COSV61278187; called by mutect2, pindel, varscan2
- VIPAS39 | c.884C>T p.T295M | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs371894407, COSV58939309; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VPS13B | c.8058G>A p.W2686* | Nonsense Mutation (SNP) | VAF 27/58 reads (47%) | catalogued as COSV62138410; called by muse, mutect2, varscan2
- VPS13B | c.10900G>A p.A3634T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs769606496, COSV62138417; called by muse, mutect2, varscan2
- VPS33A | c.246del p.F82Lfs*6 | Frame Shift Del (DEL) | VAF 24/58 reads (41%) | catalogued as rs756221452; called by mutect2, varscan2
- VPS41 | c.1615G>A p.V539I | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.596); catalogued as rs760327026, COSV59647643; called by muse, mutect2, varscan2
- WDR33 | c.2906C>A p.P969Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.077); catalogued as COSV100460623; called by muse, mutect2, varscan2
- WDR35 | c.623C>A p.A208D | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV55601781; called by muse, mutect2, varscan2
- WDR55 | c.1022del p.K341Rfs*8 | Frame Shift Del (DEL) | VAF 40/106 reads (38%) | catalogued as rs746919573; called by mutect2, varscan2
- WDR6 | c.2588T>C p.M863T | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58244634; called by muse, mutect2, varscan2
- WDR61 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV51216671; called by muse, mutect2, varscan2
- WDR62 | c.4207C>T p.P1403S | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.007); catalogued as COSV54333907; called by muse, mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | catalogued as rs779864368; called by mutect2, pindel, varscan2
- YTHDC1 | c.2155C>T p.R719* (on ENST00000344157 / NM_001031732.4; = p.R701* on NM_133370.4) | Nonsense Mutation (SNP) | VAF 44/110 reads (40%) | catalogued as COSV100704845; called by muse, mutect2, varscan2
- ZC3H10 | c.215G>A p.S72N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs763297077, COSV57768645; called by muse, mutect2, varscan2
- ZC3H13 | c.1720+2T>A p.X574_splice | Splice Site (SNP) | VAF 25/84 reads (30%) | catalogued as COSV99668842; called by muse, mutect2, varscan2
- ZC3H3 | c.939G>A p.W313* | Nonsense Mutation (SNP) | VAF 37/118 reads (31%) | catalogued as rs1169579926, COSV52788971; called by muse, mutect2, varscan2
- ZC3H4 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as COSV53411820; called by muse, mutect2, varscan2
- ZFHX3 | c.3167G>A p.R1056Q | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.99); catalogued as rs745871900, COSV51714434; called by muse, mutect2, varscan2
- ZNF250 | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs765798293, COSV52968814; called by muse, mutect2, varscan2
- ZNF317 | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs540055574, COSV56109134; called by muse, mutect2, varscan2
- ZNF653 | c.1401C>A p.F467L | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.523); catalogued as COSV53402521; called by muse, mutect2, varscan2
- ZNF700 | c.2059T>C p.S687P | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.798); catalogued as COSV54311774; called by muse, mutect2, varscan2
- ZNF780B | c.2359G>T p.G787W | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55463347; called by muse, mutect2, varscan2
- ZNF787 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1490943986, COSV99555762; called by muse, mutect2, varscan2
- ZNF8 | c.1384C>T p.R462* | Nonsense Mutation (SNP) | VAF 26/38 reads (68%) | catalogued as rs1192790847, COSV52187165; called by muse, mutect2, varscan2
- ZNF808 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.241); catalogued as rs758791058, COSV100707943, COSV63119379; called by muse, mutect2, varscan2
- ZNF835 | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 35/55 reads (64%) | SIFT tolerated (0.23); PolyPhen benign (0.065); catalogued as COSV73379351; called by muse, mutect2, varscan2
- ZNF862 | c.249dup p.Q84Tfs*71 | Frame Shift Ins (INS) | VAF 14/34 reads (41%) | catalogued as rs755241977; called by mutect2, varscan2
- ZSWIM5 | c.3013C>T p.R1005C | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.912); catalogued as rs772439229, COSV55799757; called by muse, mutect2, varscan2
- ABCB11 | c.3877del p.V1293Wfs*2 | Frame Shift Del (DEL) | VAF 38/125 reads (30%) | called by mutect2, pindel, varscan2
- ABCB4 | c.462del p.H155Mfs*8 | Frame Shift Del (DEL) | VAF 18/66 reads (27%) | called by mutect2, pindel, varscan2
- ALG12 | c.1407del p.F470Sfs*63 | Frame Shift Del (DEL) | VAF 13/40 reads (33%) | called by mutect2, pindel, varscan2
- APC | c.875dup p.L292Ffs*4 | Frame Shift Ins (INS) | VAF 6/28 reads (21%) | called by mutect2, pindel, varscan2
- AQR | c.894T>G p.F298L | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); called by muse, mutect2
- ARSK | c.785del p.N262Tfs*39 | Frame Shift Del (DEL) | VAF 56/162 reads (35%) | called by mutect2, pindel, varscan2
- ATP8B2 | c.1758dup p.K587Efs*10 (on ENST00000672630; = p.K554Efs*10 on NM_001367934.1 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 11/43 reads (26%) | called by mutect2, pindel, varscan2
- B3GAT3 | c.909+2T>C p.X303_splice | Splice Site (SNP) | VAF 25/50 reads (50%) | called by muse, mutect2, varscan2
- B3GAT3 | c.617_618+1del p.X206_splice | Splice Site (DEL) | VAF 12/52 reads (23%) | called by pindel, varscan2
- BAZ1A | c.2044del p.M682* | Frame Shift Del (DEL) | VAF 104/269 reads (39%) | called by mutect2, varscan2
- BOD1L1 | c.947dup p.N316Kfs*2 | Frame Shift Ins (INS) | VAF 82/182 reads (45%) | called by mutect2, varscan2
- C11orf87 | c.342del p.L115Cfs*162 | Frame Shift Del (DEL) | VAF 26/60 reads (43%) | called by mutect2, pindel, varscan2
- C9orf43 | c.566del p.P189Qfs*29 | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | called by mutect2, pindel, varscan2
- CACNG3 | c.514del p.S172Vfs*21 | Frame Shift Del (DEL) | VAF 33/100 reads (33%) | called by mutect2, pindel, varscan2
- CASP8 | c.1419del p.K473Nfs*? (on ENST00000432109 / NM_033355.3; = p.K490Nfs*? on NM_001228.4) | Frame Shift Del (DEL) | VAF 64/208 reads (31%) | called by mutect2, pindel, varscan2
- CCDC47 | c.347dup p.N116Kfs*2 | Frame Shift Ins (INS) | VAF 32/122 reads (26%) | called by mutect2, pindel, varscan2
- CEP126 | c.1887dup p.L630Tfs*5 | Frame Shift Ins (INS) | VAF 30/75 reads (40%) | called by mutect2, pindel, varscan2
- COL15A1 | c.3201del p.E1069Rfs*84 | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | called by mutect2, pindel, varscan2
- CRACD | c.3608del p.P1203Rfs*34 | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | called by mutect2, pindel, varscan2
- DCUN1D4 | c.525del p.K175Nfs*9 | Frame Shift Del (DEL) | VAF 38/120 reads (32%) | called by mutect2, pindel, varscan2
- DDX17 | c.488del p.G163Efs*20 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | called by mutect2, pindel, varscan2
- DHX38 | c.2088dup p.G697Wfs*16 | Frame Shift Ins (INS) | VAF 14/44 reads (32%) | called by mutect2, pindel, varscan2
- DOCK4 | c.869dup p.N291Efs*4 | Frame Shift Ins (INS) | VAF 32/78 reads (41%) | called by mutect2, varscan2
- DYNC2I1 | c.1240_1241dup p.E415Rfs*22 | Frame Shift Ins (INS) | VAF 28/126 reads (22%) | called by mutect2, varscan2
- EHHADH | c.1217del p.L406Cfs*35 | Frame Shift Del (DEL) | VAF 44/114 reads (39%) | called by mutect2, pindel, varscan2
- EPHA2 | c.1549del p.A517Pfs*21 | Frame Shift Del (DEL) | VAF 11/31 reads (35%) | called by mutect2, pindel, varscan2
- FGD4 | c.48del p.K16Nfs*24 | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | called by mutect2, pindel, varscan2
- FLNB | c.7765dup p.E2589Gfs*35 | Frame Shift Ins (INS) | VAF 9/41 reads (22%) | called by mutect2, pindel, varscan2
- FMN2 | c.3293del p.P1098Lfs*177 | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | called by mutect2, pindel, varscan2
- FYB2 | c.1851del p.E618Rfs*24 | Frame Shift Del (DEL) | VAF 42/108 reads (39%) | called by mutect2, varscan2
- FYB2 | c.1050dup p.E351Rfs*4 | Frame Shift Ins (INS) | VAF 58/206 reads (28%) | called by mutect2, pindel, varscan2
- GIN1 | c.126del p.K42Nfs*22 | Frame Shift Del (DEL) | VAF 25/74 reads (34%) | called by mutect2, pindel, varscan2
- GLI2 | c.92del p.K31Rfs*15 | Frame Shift Del (DEL) | VAF 5/51 reads (10%) | called by mutect2, pindel, varscan2
- GYG1 | c.687_688del p.S230Cfs*4 | Frame Shift Del (DEL) | VAF 49/183 reads (27%) | called by mutect2, pindel, varscan2
- IFNGR1 | c.696dup p.E233Rfs*9 | Frame Shift Ins (INS) | VAF 8/86 reads (9%) | called by mutect2, pindel
- JHY | c.2216del p.N739Ifs*55 | Frame Shift Del (DEL) | VAF 11/114 reads (10%) | called by mutect2, pindel, varscan2
- KCNJ8 | c.362_363dup p.T122* | Frame Shift Ins (INS) | VAF 11/34 reads (32%) | called by mutect2, varscan2
- KIAA0100 | c.955dup p.L319Pfs*9 | Frame Shift Ins (INS) | VAF 17/86 reads (20%) | called by mutect2, pindel, varscan2
- KIF1A | c.3941dup p.N1314Kfs*14 (on ENST00000320389 / NM_001379639.1; = p.N1306Kfs*14 on NM_004321.8 and 5 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 11/30 reads (37%) | called by mutect2, pindel, varscan2
- LMOD2 | c.1212dup p.K405Qfs*119 | Frame Shift Ins (INS) | VAF 17/44 reads (39%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.5); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MAP3K4 | c.391del p.T131Qfs*37 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | called by mutect2, pindel, varscan2
- MBD5 | c.3585dup p.Q1196Tfs*30 | Frame Shift Ins (INS) | VAF 18/66 reads (27%) | called by mutect2, pindel, varscan2
- MLXIP | c.1932dup p.V645Rfs*84 | Frame Shift Ins (INS) | VAF 19/56 reads (34%) | called by mutect2, pindel, varscan2
- MTMR14 | c.1869del p.S624Vfs*33 (on ENST00000296003 / NM_001077525.3; = p.S512Vfs*33 on NM_022485.5) | Frame Shift Del (DEL) | VAF 13/33 reads (39%) | called by mutect2, pindel, varscan2
- NEXMIF | c.4188G>T p.K1396N | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.982); called by muse, mutect2
- OBSCN | c.1391del p.G464Afs*14 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by pindel, varscan2
- ODF3L1 | c.507del p.N170Tfs*141 | Frame Shift Del (DEL) | VAF 9/40 reads (23%) | called by mutect2, pindel, varscan2
- OXSM | c.537del p.F179Lfs*45 | Frame Shift Del (DEL) | VAF 40/132 reads (30%) | called by mutect2, pindel, varscan2
- PCSK1 | c.2185del p.Y729Ifs*21 | Frame Shift Del (DEL) | VAF 68/187 reads (36%) | called by mutect2, varscan2
- PEG3 | c.3487T>C p.Y1163H | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.92); called by muse, mutect2
- PIGO | c.1841del p.P614Hfs*9 | Frame Shift Del (DEL) | VAF 14/45 reads (31%) | called by mutect2, pindel
- POFUT1 | c.529_531del p.Q177del | In Frame Del (DEL) | VAF 21/97 reads (22%) | called by mutect2, pindel, varscan2
- POU2F1 | c.1361del p.F454Sfs*15 (on ENST00000541643 / NM_001365848.1; = p.F477Sfs*15 on NM_002697.4) | Frame Shift Del (DEL) | VAF 14/27 reads (52%) | called by mutect2, pindel, varscan2
- PPP2R5E | c.601del p.T201Qfs*26 | Frame Shift Del (DEL) | VAF 31/102 reads (30%) | called by pindel, varscan2
- PRPF4B | c.2340del p.K780Nfs*13 | Frame Shift Del (DEL) | VAF 13/32 reads (41%) | called by mutect2, pindel, varscan2
- PTPN23 | c.2991del p.Y998Tfs*162 | Frame Shift Del (DEL) | VAF 29/101 reads (29%) | called by mutect2, pindel, varscan2
- RFX5 | c.56del p.P19Qfs*28 | Frame Shift Del (DEL) | VAF 40/62 reads (65%) | called by mutect2, pindel, varscan2
- RIN2 | c.1070del p.P357Hfs*39 (on ENST00000255006 / NM_001242581.1; = p.P308Hfs*39 on NM_018993.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | called by mutect2, pindel, varscan2
- RNF128 | c.30_31del p.F10Lfs*11 | Frame Shift Del (DEL) | VAF 75/148 reads (51%) | called by pindel, varscan2
- RSU1 | c.213del p.F71Lfs*21 | Frame Shift Del (DEL) | VAF 46/147 reads (31%) | called by mutect2, pindel, varscan2
- RTN4 | c.2007del p.V670Yfs*4 | Frame Shift Del (DEL) | VAF 39/144 reads (27%) | called by mutect2, pindel, varscan2
- SEMA6A | c.3036dup p.K1013Qfs*15 | Frame Shift Ins (INS) | VAF 23/62 reads (37%) | called by mutect2, pindel, varscan2
- SERPINB5 | c.668del p.N223Ifs*59 | Frame Shift Del (DEL) | VAF 29/93 reads (31%) | called by mutect2, pindel, varscan2
- SEZ6L2 | c.343del p.A115Qfs*9 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | called by mutect2, varscan2
- SGIP1 | c.1278del p.G427Dfs*71 | Frame Shift Del (DEL) | VAF 31/93 reads (33%) | called by mutect2, pindel, varscan2
- SH2D4B | c.978del p.W327Gfs*18 (on ENST00000646907; = p.W326Gfs*34 on NM_207372.2) | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | called by mutect2, pindel, varscan2
- SIGLEC1 | c.1293del p.H432Tfs*96 | Frame Shift Del (DEL) | VAF 5/53 reads (9%) | called by mutect2, pindel
- SIM1 | c.106C>T p.Q36* | Nonsense Mutation (SNP) | VAF 11/196 reads (6%) | called by muse, mutect2
- SLC22A16 | c.1693del p.T565Rfs*21 | Frame Shift Del (DEL) | VAF 30/86 reads (35%) | called by mutect2, pindel
- SLC25A51 | c.690dup p.P231Sfs*3 | Frame Shift Ins (INS) | VAF 75/288 reads (26%) | called by mutect2, pindel, varscan2
- SLC38A9 | c.1680del p.F560Lfs*17 | Frame Shift Del (DEL) | VAF 34/90 reads (38%) | called by mutect2, pindel, varscan2
- SLC4A11 | c.252dup p.V85Cfs*6 | Frame Shift Ins (INS) | VAF 25/68 reads (37%) | called by mutect2, varscan2
- SLX1A | c.610del p.H204Tfs*6 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, varscan2
- SMARCA4 | c.1062del p.I355Sfs*56 | Frame Shift Del (DEL) | VAF 13/37 reads (35%) | called by mutect2, pindel, varscan2
- SMO | c.2081del p.P694Lfs*82 | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | called by mutect2, pindel, varscan2
- SPARCL1 | c.20del p.F7Sfs*29 | Frame Shift Del (DEL) | VAF 70/189 reads (37%) | called by mutect2, pindel, varscan2
- STOX2 | c.795dup p.F266Ifs*11 | Frame Shift Ins (INS) | VAF 11/21 reads (52%) | called by mutect2, varscan2
- SYCP2L | c.2145del p.K715Nfs*27 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | called by mutect2, pindel, varscan2
- TCF7 | c.463del p.H155Tfs*44 | Frame Shift Del (DEL) | VAF 33/97 reads (34%) | called by mutect2, pindel, varscan2
- TMEM229B | c.382del p.A128Pfs*30 | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | called by mutect2, pindel, varscan2
- TRPM4 | c.371del p.G124Dfs*154 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | called by pindel, varscan2
- TTN | c.87789del p.G29264Afs*6 (on ENST00000591111; = p.G21840Afs*6 on NM_003319.4) | Frame Shift Del (DEL) | VAF 65/167 reads (39%) | called by mutect2, varscan2
- UTP4 | c.2042del p.K681Rfs*? | Frame Shift Del (DEL) | VAF 36/107 reads (34%) | called by mutect2, pindel, varscan2
- VIRMA | c.2163del p.F721Lfs*11 | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | called by mutect2, varscan2
- WAC | c.1036_1044del p.S346_V348del | In Frame Del (DEL) | VAF 28/57 reads (49%) | called by mutect2, pindel, varscan2
- XPO5 | c.1127dup p.A377Sfs*6 | Frame Shift Ins (INS) | VAF 15/46 reads (33%) | called by mutect2, pindel, varscan2
- ZCCHC14 | c.329del p.N110Mfs*18 (on ENST00000268616; = p.N247Mfs*18 on NM_015144.3) | Frame Shift Del (DEL) | VAF 20/71 reads (28%) | called by mutect2, pindel, varscan2
- ZFPM1 | c.738_739del p.C246Wfs*135 | Frame Shift Del (DEL) | VAF 20/70 reads (29%) | called by pindel, varscan2
- ZNF34 | c.663_664dup p.T222Kfs*16 | Frame Shift Ins (INS) | VAF 22/133 reads (17%) | called by mutect2, varscan2
- ZNF646 | c.1590del p.S531Afs*5 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | called by mutect2, pindel, varscan2
- ABL1 | c.2697G>A p.P899= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs367911374; called by muse, varscan2
- ADAM15 | c.2421G>A p.P807= (on ENST00000356955 / NM_207197.3; = p.P782= on NM_207195.3) | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs759494843, COSV55126093; called by muse, mutect2, varscan2
- ADCY9 | c.2844G>A p.S948= | Silent (SNP) | VAF 46/118 reads (39%) | catalogued as rs137924284; called by muse, mutect2, varscan2
- ADD1 | c.2106C>T p.A702= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as rs34737322; called by muse, mutect2, varscan2
- AHNAK | c.5439G>A p.P1813= | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as rs201325865, COSV57209992; called by muse, mutect2, varscan2
- AJAP1 | c.270C>T p.H90= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs1484887123, COSV65450208; called by muse, mutect2, varscan2
- ALMS1 | c.6165T>C p.N2055= | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as COSV52507317; called by muse, mutect2, varscan2
- AMOTL2 | c.1692C>T p.A564= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs758990000, COSV51438420, COSV99850664; called by muse, mutect2, varscan2
- ARHGEF10 | c.2151C>T p.G717= (on ENST00000398564; = p.G692= on NM_014629.4) | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs1310735172, COSV50645645; called by muse, mutect2, varscan2
- ARHGEF18 | c.840C>T p.D280= (on ENST00000359920 / NM_001130955.2; = p.D176= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV60468683; called by muse, mutect2
- ARHGEF4 | c.1323G>A p.T441= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as rs1483318405, COSV58120480, COSV58127588; called by muse, mutect2, varscan2
- ATP13A2 | c.1494A>G p.P498= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV58699673; called by muse, mutect2, varscan2
- ATP9A | c.1827G>A p.E609= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs1401049455, COSV58765094; called by muse, mutect2
- B3GAT1 | c.174G>A p.T58= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as rs755439844, COSV56996037; called by muse, mutect2, varscan2
- BAHCC1 | c.4503G>A p.T1501= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs782317986, COSV100312036, COSV57025135; called by muse, mutect2, varscan2
- BCL6 | c.1611G>A p.T537= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as rs142294621; called by muse, mutect2, varscan2
- BRF2 | c.672C>T p.P224= | Silent (SNP) | VAF 34/124 reads (27%) | catalogued as rs372185215, COSV55103219; called by muse, mutect2, varscan2
- BSCL2 | c.654G>A p.A218= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as rs375554369, COSV54017103; ClinVar: likely benign; called by muse, mutect2, varscan2
- BTD | c.1377G>A p.T459= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as rs535292517, COSV57728946; called by muse, mutect2, varscan2
- BTF3 | c.243C>T p.A81= (on ENST00000380591 / NM_001037637.1; = p.A37= on NM_001207.4) | Silent (SNP) | VAF 56/137 reads (41%) | catalogued as rs1424714855, COSV60063310; called by muse, mutect2, varscan2
- C11orf16 | c.48C>T p.S16= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs745603948, COSV58166504, COSV58166872; called by muse, mutect2, varscan2
- C15orf39 | c.1320C>A p.T440= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV62296255; called by muse, mutect2, varscan2
- C18orf25 | c.834C>T p.G278= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as rs367632018; called by muse, mutect2, varscan2
- C1orf127 | c.654C>T p.T218= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as rs138123175; called by muse, mutect2, varscan2
- CACNG6 | c.585C>T p.S195= (on ENST00000252729 / NM_145814.1; = p.S124= on NM_031897.2) | Silent (SNP) | VAF 36/73 reads (49%) | catalogued as COSV53166304, COSV53166640; called by muse, mutect2, varscan2
- CALR | c.318G>T p.G106= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV57122151; called by muse, mutect2, varscan2
- CASKIN2 | c.975C>T p.H325= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs776069638, COSV58594634; called by muse, mutect2, varscan2
- CDH2 | c.1830A>G p.A610= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as rs1362820537, COSV52276568; called by muse, mutect2, varscan2
- CDYL2 | c.1419C>T p.D473= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs746278663, COSV73653979; called by muse, varscan2
- CEACAM7 | c.372C>T p.H124= | Silent (SNP) | VAF 129/372 reads (35%) | catalogued as rs138765616; called by muse, mutect2, varscan2
- CEP170B | c.2838G>A p.P946= (on ENST00000453495; = p.P875= on NM_015005.3) | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs199921376, COSV69024022; called by muse, mutect2, varscan2
- CEP170B | c.4089C>T p.S1363= (on ENST00000453495; = p.S1292= on NM_015005.3) | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as rs368360916; called by muse, mutect2, varscan2
- CFAP100 | c.1065C>T p.S355= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs767475855, COSV61502796, COSV61504062; called by muse, mutect2, varscan2
- CHGA | c.687G>A p.E229= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV53662864; called by muse, mutect2, varscan2
- CLK4 | c.216C>T p.Y72= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as rs759142609, COSV60318264; called by muse, mutect2, varscan2
- CNPPD1 | c.468G>A p.V156= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV55406327; called by muse, mutect2, varscan2
- CNTN2 | c.2967C>T p.P989= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs766320758, COSV59349371; called by muse, mutect2, varscan2
- CNTN3 | c.1206A>G p.K402= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as COSV55167683; called by muse, mutect2, varscan2
- CRHR2 | c.861C>T p.V287= | Silent (SNP) | VAF 37/84 reads (44%) | catalogued as COSV59264592; called by muse, mutect2, varscan2
- CTTN | c.546G>A p.T182= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs542706268, COSV57231488; called by muse, mutect2, varscan2
- CYP21A2 | c.123G>A p.L41= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as rs1349496588, COSV100926605; called by muse, varscan2
- DDIT4L | c.294G>A p.T98= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs141348282; called by muse, mutect2, varscan2
- DDX39A | c.876C>T p.F292= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs371615674; called by muse, mutect2, varscan2
- DEFB136 | c.81A>C p.G27= | Silent (SNP) | VAF 34/106 reads (32%) | catalogued as rs748651102, COSV66363821; called by muse, mutect2, varscan2
- DHDH | c.807G>A p.P269= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs369662956, COSV55481902; called by muse, mutect2
- DMBT1 | c.6960C>T p.I2320= (on ENST00000338354 / NM_001377530.1; = p.I1563= on NM_004406.3) | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as rs763791912, COSV57540113; called by muse, mutect2, varscan2
- DNA2 | c.1755G>A p.T585= | Silent (SNP) | VAF 60/141 reads (43%) | catalogued as rs577208486, COSV64428175; called by muse, mutect2, varscan2
- DNAAF5 | c.1287G>A p.T429= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs143584365; called by muse, mutect2, varscan2
- DNAH7 | c.7938T>C p.A2646= | Silent (SNP) | VAF 88/225 reads (39%) | catalogued as COSV56759086; called by muse, mutect2, varscan2
- DSCAML1 | c.5283C>T p.G1761= (on ENST00000321322; = p.G1701= on NM_020693.4) | Silent (SNP) | VAF 45/113 reads (40%) | catalogued as rs1468914313, COSV58387492; called by muse, mutect2, varscan2
- DZIP1 | c.2412A>G p.G804= (on ENST00000347108; = p.G785= on NM_014934.5) | Silent (SNP) | VAF 67/152 reads (44%) | catalogued as rs200670080, COSV61265000, COSV61265349; called by muse, mutect2, varscan2
- ECI1 | c.642G>A p.P214= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs776709883, COSV57043256; called by muse, mutect2, varscan2
- ELOVL3 | c.81G>A p.R27= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs769553336, COSV64174286, COSV64174288; called by muse, mutect2, varscan2
- ENO3 | c.462C>T p.N154= | Silent (SNP) | VAF 11/17 reads (65%) | catalogued as rs902764196, COSV52776883; called by muse, mutect2, varscan2
- EPC2 | c.1797C>A p.A599= | Silent (SNP) | VAF 68/226 reads (30%) | catalogued as COSV51542680; called by muse, varscan2
- EVPL | c.5031G>A p.T1677= | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as rs750140523, COSV56909492; called by muse, mutect2, varscan2
- F2 | c.822C>T p.C274= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as COSV61315123; called by muse, mutect2
- FAM47A | c.1407G>A p.Q469= | Silent (SNP) | VAF 29/34 reads (85%) | catalogued as COSV60495067; called by muse, mutect2, varscan2
- FBN1 | c.2433C>T p.C811= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as rs193921256, CM042037, CM096439, COSV57313913; ClinVar: likely benign; called by muse, mutect2, varscan2
- FBXO15 | c.345C>T p.I115= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as rs775099298, COSV54044170; called by muse, mutect2, varscan2
- FER1L5 | c.6150C>T p.N2050= (on ENST00000623019; = p.N2014= on NM_001293083.2) | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as rs552412694, COSV53841295; called by muse, mutect2, varscan2
- FFAR4 | c.948G>A p.P316= | Silent (SNP) | VAF 52/150 reads (35%) | catalogued as rs113451789, COSV65159917; called by muse, mutect2, varscan2
- FGG | c.630C>T p.I210= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs148688900, COSV60195003, COSV60196402; called by muse, mutect2, varscan2
- FOXK1 | c.2037G>A p.T679= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as rs111856572, COSV61065368; called by muse, mutect2, varscan2
- FOXN3 | c.1188C>T p.D396= (on ENST00000261302; = p.D374= on NM_005197.4) | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as rs143673672; called by muse, mutect2, varscan2
- GEMIN5 | c.3855G>A p.L1285= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as COSV53559702; called by muse, mutect2, varscan2
- GEMIN5 | c.2271G>A p.S757= | Silent (SNP) | VAF 76/210 reads (36%) | catalogued as rs777425419, COSV53559132; called by muse, mutect2, varscan2
- GLUL | c.930C>T p.N310= | Silent (SNP) | VAF 32/95 reads (34%) | catalogued as rs369280031; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR37L1 | c.783G>A p.T261= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs567590167, COSV66162098; called by muse, mutect2, varscan2
- GPR84 | c.49C>T p.L17= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV57209316; called by muse, mutect2, varscan2
- GRM2 | c.1488C>T p.P496= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as rs777119324, COSV56583961; called by muse, mutect2, varscan2
- GSE1 | c.804C>T p.D268= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as rs777956991, COSV53670990; called by muse, mutect2, varscan2
130 further variants in this file (0 protein-altering or splice-affecting, 113 silent, 17 other) are not listed here.
